Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NK-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

REVISED REPORT (Addendum/Procedure included)
Requested By:

Site: Liver C22.0

JW
12/24/12

TISSUE DESCRIPTION:

A1 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9

Right liver (1,205 grams; 18.0 x 12.0 x 8.0 cm), gallbladder (11 x 3.5 x 2.0 cm), and pericholedochal lymph node (2.2 x 1.2 x 0.8 cm).

DIAGNOSIS:

Liver, right, hepatectomy: Grade 2 (of 4) hepatocellular carcinoma forming a 12.2 x 10.0 x 8.0 cm hepatic mass. Multiple (>30) adjacent tumor nodules, ranging in size from 0.1 cm to 2.5 cm, are also identified. The surgical margin is negative for tumor (closest tumor free margin is 0.2 cm).

Lymph node, pericholedochal, excision: A single pericholedochal lymph node is negative for tumor.

Gallbladder, cholecystectomy: Chronic cholecystitis and cholelithiasis with multiple (>50) mixed stones ranging in size from 0.1 to 0.4 cm in greatest dimension.

ADDENDUM:

The adjacent hepatic parenchyma is non-cirrhotic.

ADDENDUM:

A trichrome stain shows no abnormal fibrosis. An iron stain is negative for hemosiderosis. Alpha-1-antitrypsin is negative for cytoplasmic globules. Vascular invasion is not seen.

Source: NCI Genomic Data Commons file 37bcf287-a6b8-4304-80a3-c6e623510158 (TCGA-DD-A4NK.0521278C-B2AC-4D7D-BC1F-5003B630808E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).